Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A3HQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A3HQ-01A (Primary Tumor).

Procurement Date: Laterality:

Path Report: CERVIX TISSUE CHECKLIST

Specimen type: Hysterectomy, bilateral salpingo-oophorectomy

Tumor site: Cervix

Tumor size: 4 x 3 x 3 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Lesion less than 4.0 cm

Lymph nodes: 0/13 positive for metastasis (Regional 0/13)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Gross Description:

Microscopic Description:

Diagnosis Details:

1C8-0-3
carcinoma, squamous cell 8070/3
Site: cervix, NOS C53.9 w 12/1/11

Dx at Synchronous Primary Noted		X

Source: NCI Genomic Data Commons file 4720e603-6b3b-4e93-990f-21a23ea7e8d7 (TCGA-EA-A3HQ.868FEAAA-6A22-47A9-A309-49119D36E75E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).